Surgical pathology report (de-identified scan), TCGA case TCGA-CZ-5465, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Harvard, specimen TCGA-CZ-5465-01A (Primary Tumor).

[page 1 of 3]
Accession Number: [REDACTED] Report Status: Amend/Add
Type: Surgical Pathology
Specimen Type: Kidney, partial or total resection
Procedure Date: [REDACTED]
Ordering Provider: [REDACTED]

CASE: [REDACTED]
PATIENT: [REDACTED]

***** Addended Report *****

TCGA-CZ-5465

PATHOLOGIC DIAGNOSIS:

SPECIMEN DESIGNATED "LEFT KIDNEY (323.5g):
RENAL CELL CARCINOMA, clear cell (conventional) type (5.6 cm),
Fuhrman nuclear grade 2 (of 4).
Soft tissue, ureteral, and vascular margins are negative for tumor.
The tumor extends into the renal vein.
The tumor does not invade renal capsule.
No lymphovascular invasion identified.
Adrenal gland, negative for tumor.

The non-neoplastic kidney will be evaluated by Renal Pathology, and the findings will be reported in an addendum.

AJCC Classification (6th Edition): pT3b Nx MX

CLINICAL DATA:

History: None given.
Operation: Left radical nephrectomy.
Operative Findings: None given.
Clinical Diagnosis: Renal cell CA.

TISSUE SUBMITTED:

A/1. Left kidney.

GROSS DESCRIPTION:

The specimen is received fresh, labeled with the patient's name, unit number, and "#1. Left kidney", consists of a left kidney (323.5 g, 16.7 x 8.8 x 5.1 cm), to include a ureter (7.8 x 0.2 cm), artery (0.7 x 0.4 cm), and vein (0.5 x 0.7 cm). The kidney is encapsulated by Gerota's fascia consisting of tan/yellow lobulated adipose tissue. Sectioning of the specimen shows a tan/pink to tan/yellow, interpolar, irregular mass (5.6 x 5.0 x 5.0 cm) that is partially encapsulated. The mass is 2.5 cm to the arterial margin, 2.5 cm to the renal vein margin, and 10.5 cm to the ureteral margin. The mass disrupts two-thirds of the renal parenchyma, and abuts the kidney capsule, coming to within less than 0.1 cm of the inked margin. The tumor also grossly extends into the renal vein. The unremarkable urothelium is tan/gray smooth and glistening and unremarkable. The remaining renal parenchyma is tan/brown and has a focally well defined corticomedullary junction. Sectioning of the perirenal adipose tissue (2.0 x 1.4 x 1.0 cm) shows a centrally hemorrhagic medulla, surrounded by a tan/yellow cortex. Further sectioning of the perirenal adipose tissue shows no lymph nodes.

Micro A1-A2: Section of tumor to capsule and surrounding pericolic adipose tissue, 2 frags, [REDACTED]

Micro A3: Section of tumor to normal kidney, 1 frag, [REDACTED]

Micro A4: Renal vein, renal artery, and ureteral margins, 1 frag, [REDACTED]

Micro A5: Section of tumor extending to renal vein, 2 frags, [REDACTED]

Micro A6: Normal kidney, 1 frag, [REDACTED]

Micro A7: Section of adrenal, 1 frag, [REDACTED]

By his/her signature below, the senior physician certifies that he/she

[page 2 of 3]
TCGA-CZ-5465

[page 3 of 3]
Accession Number: [REDACTED]
Type: Cytogenetics
CASE: [REDACTED]
PATIENT: [REDACTED]
Cytogene[REDACTED]

Report Status: Final

KARYOTYPE:

72-83<4n>,XXXX,-1,der(3)t(3;8)(p1?3;q1?3)x2,-4,add(7)(q3?5)x2,-8,-8,-9,
-10,-15,-17,-18[cp5]

METAPHASES COUNTED: 5

ANALYZED: 5

SCORED: 0

BANDING: GTG

INTERPRETATION:

All metaphases contained the clonal aberrations described above. Loss of the short arm of chromosome 3 is a characteristic finding in renal cell carcinoma, clear cell type.

COMMENTS:

Mosaicism and small chromosome anomalies may not be detectable using the standard methods employed. Chromosome analysis was performed at a level of 400 bands or greater.

INDICATION FOR TEST:

RCC

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 332c96a8-0a23-4274-ab3c-e0f2131feac8 (TCGA-CZ-5465.0C23F13D-0910-4835-B9FA-06F10736B2DD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).